Somatic mutation profile of tumor specimen TCGA-AR-A0TW-01A (aliquot TCGA-AR-A0TW-01A-11D-A099-09) from TCGA case TCGA-AR-A0TW, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 50.0 years (18,263 days).
Specimen TCGA-AR-A0TW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2bc7c615-bcbe-4507-a7d7-1e6faa91a4cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A0TW-10A (Blood Derived Normal), aliquot TCGA-AR-A0TW-10A-01D-A099-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a0a43ae-7614-43ef-a816-4008b24952ca

The open-access MAF lists 56 somatic variants for this specimen: 40 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 14, Nonsense Mutation 5, Splice Site 2, Frame Shift Del 2, Frame Shift Ins 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOXL | c.1496G>T p.C499F (on ENST00000389811 / NM_001371254.1; = p.C469F on NM_001142807.4) | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV101094905; called by muse, mutect2, varscan2
- ADAM21 | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.124); catalogued as rs758298943, COSV99960987; called by muse, mutect2, varscan2
- ADGRG4 | c.7317G>T p.K2439N | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV99795423; called by muse, mutect2, varscan2
- API5 | c.1275C>G p.I425M | Missense Mutation (SNP) | VAF 97/262 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101124535; called by muse, mutect2, varscan2
- CDC42BPA | c.3008C>G p.S1003* (on ENST00000334218 / NM_001366019.2; = p.S990* on NM_003607.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 31/290 reads (11%) | catalogued as rs775202925, COSV100505048; called by muse, mutect2, varscan2
- COL11A1 | c.2143-1G>T p.X715_splice | Splice Site (SNP) | VAF 8/53 reads (15%) | catalogued as COSV100616471, COSV62176001; called by muse, mutect2, varscan2
- DALRD3 | c.1226G>A p.R409H (on ENST00000341949 / NM_001009996.3; = p.R242H on NM_018114.5) | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs895634160, COSV100482817; called by muse, mutect2, varscan2
- DKC1 | c.58A>G p.K20E | Missense Mutation (SNP) | VAF 80/393 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.196); catalogued as COSV101059879; called by muse, mutect2, varscan2
- DOCK7 | c.4054T>G p.S1352A (on ENST00000635253 / NM_001367561.1; = p.S1321A on NM_033407.3) | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV99224353; called by muse, mutect2, varscan2
- DPYSL2 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs143980725; called by muse, mutect2, varscan2
- GDI1 | c.478G>C p.G160R | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV99341027; called by muse, mutect2, varscan2
- GK2 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 31/232 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100725953; called by muse, mutect2, varscan2
- GLT1D1 | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.772); catalogued as COSV99896628; called by muse, mutect2, varscan2
- GRIA1 | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.069); catalogued as rs545946719, COSV53601676; called by muse, mutect2, varscan2
- GRIN2A | c.964G>T p.G322W | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100409746; called by muse, mutect2, varscan2
- HSPD1 | c.390G>T p.K130N | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV99291463; called by muse, mutect2, varscan2
- LAMA5 | c.4897G>A p.A1633T | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.634); catalogued as rs1235384284, COSV99439906; called by muse, mutect2, varscan2
- MESP2 | c.1038T>A p.S346R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV100510755; called by muse, mutect2
- MTMR14 | c.1297C>T p.R433* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as rs750945377, COSV56004664; called by muse, mutect2, varscan2
- NCOR1 | c.5560A>T p.R1854* | Nonsense Mutation (SNP) | VAF 18/27 reads (67%) | catalogued as COSV99249819; called by muse, mutect2, varscan2
- PCDHA13 | c.451C>T p.R151* | Nonsense Mutation (SNP) | VAF 16/93 reads (17%) | catalogued as COSV99166256; called by muse, mutect2, varscan2
- PKHD1 | c.10512G>T p.Q3504H | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100944210; called by muse, mutect2, varscan2
- PNPLA4 | c.680G>A p.S227N | Missense Mutation (SNP) | VAF 26/231 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV101124389; called by muse, mutect2, varscan2
- PNPLA4 | c.679A>T p.S227C | Missense Mutation (SNP) | VAF 26/234 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.379); catalogued as COSV101124391; called by muse, mutect2, varscan2
- SAMD9 | c.2669C>A p.T890N | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV101180251; called by muse, mutect2, varscan2
- SIMC1 | c.2152C>T p.R718C (on ENST00000443967 / NM_001308196.1; = p.R303C on NM_198567.5) | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs564067290, COSV100231112; called by muse, mutect2, varscan2
- SLC25A21 | c.549C>G p.N183K | Missense Mutation (SNP) | VAF 63/199 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100491237, COSV58728954; called by muse, mutect2, varscan2
- SLC44A5 | c.1624+1G>A p.X542_splice | Splice Site (SNP) | VAF 52/122 reads (43%) | catalogued as rs757242110, COSV63768816; called by muse, mutect2, varscan2
- STK11IP | c.1724G>T p.R575L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV55247067, COSV99822814; called by muse, mutect2
- TMCO3 | c.1915C>T p.R639W | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1299450735, COSV64807880; called by muse, mutect2, varscan2
- TRIOBP | c.2179C>T p.R727W | Missense Mutation (SNP) | VAF 57/239 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as rs1270705836, COSV60384604, COSV60385285; called by muse, mutect2, varscan2
- WDR17 | c.2535G>T p.W845C | Missense Mutation (SNP) | VAF 37/257 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1005312701, COSV99707564; called by muse, mutect2, varscan2
- ZNF160 | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as rs757419776, COSV61999210; called by muse, mutect2, varscan2
- ZNF521 | c.2635G>A p.V879I | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs201246445, COSV64124791, COSV64126644; called by muse, mutect2, varscan2
- ZNF648 | c.1517G>T p.C506F | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100374590; called by muse, mutect2, varscan2
- ACACB | c.7313G>T p.S2438I | Missense Mutation (SNP) | VAF 2/11 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.345); called by muse, mutect2
- CAMSAP3 | c.3502C>T p.Q1168* | Nonsense Mutation (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2, varscan2
- GATA3 | c.1200dup p.S401Vfs*106 | Frame Shift Ins (INS) | VAF 18/73 reads (25%) | called by mutect2, pindel, varscan2
- MSH4 | c.659del p.N220Ifs*8 | Frame Shift Del (DEL) | VAF 81/211 reads (38%) | called by mutect2, pindel, varscan2
- RASSF2 | c.70_74del p.L24Afs*10 | Frame Shift Del (DEL) | VAF 14/170 reads (8%) | called by mutect2, pindel
- ACTG2 | c.21C>T p.T7= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs750129394, COSV61829141, COSV61830281; called by muse, mutect2
- CDKL5 | c.183T>G p.L61= | Silent (SNP) | VAF 40/380 reads (11%) | catalogued as CD043175, COSV101184305; called by muse, mutect2, varscan2
- CNOT1 | c.1623A>G p.A541= | Silent (SNP) | VAF 34/174 reads (20%) | catalogued as COSV100409276; called by muse, mutect2, varscan2
- COL11A2 | c.3882C>T p.G1294= (on ENST00000341947 / NM_080680.3; = p.G1187= on NM_080679.2) | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as rs752282200, COSV100553986; called by muse, mutect2
- EVPL | c.4362C>T p.P1454= | Silent (SNP) | VAF 25/39 reads (64%) | catalogued as COSV100044481; called by muse, mutect2, varscan2
- FAT3 | c.7782T>C p.N2594= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as COSV99965952; called by muse, mutect2, varscan2
- KLK7 | c.681C>G p.G227= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as rs758335462, COSV100304418; called by muse, mutect2, varscan2
- PITPNC1 | c.750C>T p.G250= | Silent (SNP) | VAF 19/569 reads (3%) | catalogued as COSV100083420; called by muse, mutect2
- PXDNL | c.3633G>T p.V1211= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as COSV100683555; called by muse, mutect2, varscan2
- RFC1 | c.2901G>A p.S967= (on ENST00000381897 / NM_001363496.2; = p.S966= on NM_002913.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/120 reads (11%) | catalogued as rs747832718, COSV100567668; called by muse, mutect2, varscan2
- SPICE1 | c.1500C>T p.F500= | Silent (SNP) | VAF 27/137 reads (20%) | catalogued as COSV99871348; called by muse, mutect2, varscan2
- TRIM6 | c.688C>T p.L230= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV99546400; called by muse, mutect2, varscan2
- YTHDF1 | c.1506C>T p.V502= | Silent (SNP) | VAF 79/231 reads (34%) | catalogued as COSV100945565; called by muse, mutect2, varscan2
- YTHDF1 | c.1266C>T p.D422= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs375948144; called by muse, varscan2
- PRKCA | c.1713+161C>T | Intron (SNP) | VAF 38/277 reads (14%) | catalogued as COSV101151252; called by muse, mutect2
- ZSCAN32 | chr16:3382988 T>C | 3'Flank (SNP) | VAF 36/206 reads (17%) | catalogued as COSV100514360; called by muse, mutect2, varscan2
